TCGA case TCGA-3U-A98I — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5ad9aef-27c6-4101-befb-6227cd1266ba

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 860 days (2.4 years).

Diagnoses (4)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 68.7 years (25,108 days); Year of diagnosis: 2013; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 860 days (2.4 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed; Days to treatment start: 74 days; Days to treatment end: 215 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 439 days (1.2 years); Days to treatment end: 467 days (1.3 years); Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 551 days (1.5 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant). Age at diagnosis: 69.8 years (25,512 days); Days to diagnosis: 404 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 69.8 years (25,512 days); Days to diagnosis: 404 days (1.1 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Lung, NOS. Age at diagnosis: 70.3 years (25,659 days); Days to diagnosis: 551 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (9 entries)
- Day 404 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 404 days (1.1 years).
- Days to follow up: 439 days (1.2 years); Disease response: With Tumor.
- Day 551 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 551 days (1.5 years).
- Day 551 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 551 days (1.5 years).
- Days to follow up: 671 days (1.8 years); Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 9.4; Timepoint: Prior to Treatment.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.
- Follow-up contact recording only the day: day 860.

Molecular and laboratory tests
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.4].

Exposures
- Occupation type: Armed Forces Occupations, Other Ranks.
- Exposure type: Asbestos; Age at onset: 22; Exposure duration years: 34; Exposure source: Occupational.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Grandparent; Relationship primary diagnosis: Gastric Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3U-A98I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 420 mg.
  Slide TCGA-3U-A98I-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-3U-A98I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3U-A98I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Submarine worker in Navy and then engineer in a nuclear power plant; Performance status timing: Post-Adjuvant Therapy.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma; Mesothelioma detection method: Thorascopy.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 2: Clinical trial drug classification: anti-CTLA4 monoclonal antibody.
- Drug treatment 4: Pharmaceutical therapy drug name: Pemetrexed (Alimta).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 860 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 860 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 404 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3U-A98I-01A-11D-A39Q-01): tumor purity 0.52, ploidy 1.78, whole-genome doublings 0.
